EXCEPTIONAL_RESPONDERS case ER-ABV2 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c98e5b8f-3726-4ed7-a83f-5d09543a2a22

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 53.4 years (19,505 days); Year of diagnosis: 2005; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 3,616 days (9.9 years); Days to best overall response: 636 days (1.7 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Docetaxel; Days to treatment start: 489 days (1.3 years); Days to treatment end: 601 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 3,616 days (9.9 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 3,616 days (9.9 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABV2-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABV2-TTM1-B-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide ER-ABV2-TTM1-A-1-0-S2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 10; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
